Somatic mutation profile of tumor specimen TCGA-B0-4852-01A (aliquot TCGA-B0-4852-01A-01D-1501-10) from TCGA case TCGA-B0-4852, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 78.2 years (28,552 days).
Specimen TCGA-B0-4852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08cfcd71-5a25-4c44-a2bb-1da019a8ad54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4852-11A (Solid Tissue Normal), aliquot TCGA-B0-4852-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5109873d-a6e1-4b2b-bd52-aa70f17769b9

The open-access MAF lists 89 somatic variants for this specimen: 71 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Frame Shift Ins 6, Splice Site 6, Frame Shift Del 6, Intron 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-2A>G p.X155_splice | Splice Site (SNP) | VAF 72/152 reads (47%) | hotspot (GDC flag); catalogued as rs5030816, CS941546, CS961704, CS961705, COSV56547121, COSV56551502, COSV56558899, COSV56563919; ClinVar: pathogenic; called by muse, varscan2
- AAK1 | c.2711T>C p.F904S | Missense Mutation (SNP) | VAF 151/437 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV68645076; called by muse, mutect2, varscan2
- ACTG1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV59511060; called by muse, mutect2, varscan2
- ADAMTS6 | c.2910+1G>C p.X970_splice | Splice Site (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100068419, COSV58683939; called by muse, mutect2, varscan2
- ADCK2 | c.1523T>A p.F508Y | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50782181; called by muse, mutect2, varscan2
- ADGRE3 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 187/526 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs1359111638, COSV53728546; called by muse, mutect2, varscan2
- ATP10D | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 26/604 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs185611178, COSV56707787; called by muse, mutect2
- ATP13A4 | c.2443T>G p.L815V | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.708); catalogued as COSV61322022; called by muse, mutect2, varscan2
- AUP1 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57817915; called by muse, mutect2, varscan2
- AVIL | c.1166T>C p.M389T | Missense Mutation (SNP) | VAF 126/414 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57682573; called by muse, mutect2, varscan2
- BCL9 | c.3725C>A p.S1242Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52346720; called by muse, mutect2, varscan2
- BUB3 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV64363984; called by muse, mutect2, varscan2
- CD1E | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV63771741; called by muse, mutect2, varscan2
- CLTA | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 38/734 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54255091; called by muse, mutect2
- CLTC | c.2608T>C p.C870R | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52249332; called by muse, mutect2, varscan2
- CNTRL | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 81/229 reads (35%) | catalogued as COSV53049412; called by muse, mutect2, varscan2
- COL4A5 | c.4262G>T p.G1421V | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60365147; called by muse, mutect2, varscan2
- CTSL | c.213_214del p.H71Qfs*15 | Frame Shift Del (DEL) | VAF 112/452 reads (25%) | catalogued as rs1324954659; called by pindel, varscan2
- DIP2C | c.3640C>A p.P1214T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV55165699; called by muse, mutect2
- DMXL2 | c.8927T>C p.L2976P | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51849819; called by muse, mutect2, varscan2
- DMXL2 | c.591G>C p.W197C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51848450, COSV51849829; called by muse, mutect2, varscan2
- F8 | c.6163C>T p.Q2055* | Nonsense Mutation (SNP) | VAF 118/344 reads (34%) | catalogued as CM123848, COSV64275411; called by muse, mutect2, varscan2
- FAM135A | c.2571A>C p.K857N (on ENST00000370479 / NM_001351599.1; = p.K644N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.265); catalogued as COSV52054214; called by muse, mutect2
- FBLN1 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as COSV53049828; called by muse, mutect2, varscan2
- FLG2 | c.6460A>C p.T2154P | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV66170161; called by muse, mutect2
- HCLS1 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV58857913; called by muse, mutect2, varscan2
- IGHD | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 19/325 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV101163059; called by muse, mutect2
- ITPRIP | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV53392178; called by muse, mutect2, varscan2
- KCNG3 | c.941T>C p.L314S | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60149939; called by muse, mutect2
- KLHL15 | c.713C>A p.T238K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.259); catalogued as COSV60140918; called by muse, mutect2
- KLHL7 | c.754C>G p.L252V (on ENST00000339077 / NM_001031710.3; = p.L204V on NM_018846.5) | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV59162496; called by muse, mutect2, varscan2
- MAPK1 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53187429; called by muse, mutect2
- MARCHF1 | c.742C>A p.L248M (on ENST00000274056; = p.L231M on NM_017923.4) | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV56821062; called by muse, mutect2, varscan2
- MED12L | c.726+1G>T p.X242_splice | Splice Site (SNP) | VAF 62/192 reads (32%) | catalogued as COSV56385331; called by muse, varscan2
- MED23 | c.1408A>C p.N470H | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.421); catalogued as COSV63433989; called by muse, mutect2
- MLXIP | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59836472; called by muse, mutect2
- MSL3 | c.1126G>A p.D376N (on ENST00000312196 / NM_078629.4; = p.D210N on NM_006800.4) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV56494359; called by muse, mutect2
- MTOR | c.6098A>T p.E2033V | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV63874026; called by mutect2, varscan2
- NHLRC2 | c.1709C>G p.P570R | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs775341325, COSV65175287; called by muse, mutect2, varscan2
- OCRL | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 106/330 reads (32%) | catalogued as COSV63981250; called by muse, mutect2, varscan2
- OPRM1 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57679855, COSV57679871; called by muse, mutect2, varscan2
- OR3A2 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs935160496, COSV68695153; called by muse, mutect2, varscan2
- OTOF | c.5275G>T p.D1759Y (on ENST00000272371 / NM_194248.3; = p.D992Y on NM_004802.4) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55508320, COSV55524105; called by muse, mutect2, varscan2
- PBRM1 | c.2927del p.H976Lfs*38 (on ENST00000296302 / NM_001366071.2; = p.H976Lfs*32 on NM_018313.5) | Frame Shift Del (DEL) | VAF 80/186 reads (43%) | catalogued as COSV56285717; called by mutect2, pindel, varscan2
- PCP4L1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1430625368, COSV73440715; called by muse, mutect2
- PPP2R5A | c.394T>A p.F132I | Missense Mutation (SNP) | VAF 145/406 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV54816996; called by muse, mutect2, varscan2
- PRRG3 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64851249; called by muse, mutect2, varscan2
- SCN7A | c.2333T>A p.M778K | Missense Mutation (SNP) | VAF 92/584 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1403665819, COSV69272789; called by muse, mutect2, varscan2
- SEC24D | c.914-1G>A p.X305_splice | Splice Site (SNP) | VAF 66/178 reads (37%) | catalogued as COSV54881598; called by muse, mutect2, varscan2
- SENP6 | c.507A>C p.K169N | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV59192298; called by muse, mutect2
- SERPINB11 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.572); catalogued as COSV66957196, COSV66957290; called by muse, mutect2
- SETD2 | c.4880T>G p.M1627R | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57442293; called by muse, mutect2
- SIGLECL1 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57063417; called by muse, mutect2, varscan2
- TMCC3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54155510; called by muse, mutect2, varscan2
- UBA1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60113654; called by muse, mutect2, varscan2
- USP18 | c.239C>A p.T80N | Missense Mutation (SNP) | VAF 124/437 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV53173877; called by muse, mutect2, varscan2
- VPS18 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs754471003, COSV55031167; called by muse, mutect2, varscan2
- ZBTB46 | c.938-1G>A p.X313_splice | Splice Site (SNP) | VAF 19/43 reads (44%) | catalogued as COSV55511777; called by muse, varscan2
- ZFAND2B | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV54697445, COSV54698660; called by muse, mutect2, varscan2
- ZNF570 | c.1163G>T p.C388F | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57579809; called by muse, mutect2, varscan2
- ACACA | c.472-2A>G p.X158_splice | Splice Site (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- CCAR1 | c.2012_2016del p.K671Rfs*14 | Frame Shift Del (DEL) | VAF 127/454 reads (28%) | called by mutect2, pindel, varscan2
- DNAH8 | c.12527del p.P4176Lfs*54 | Frame Shift Del (DEL) | VAF 135/549 reads (25%) | called by mutect2, pindel, varscan2
- FAT1 | c.6631_6655del p.G2211Qfs*21 | Frame Shift Del (DEL) | VAF 45/176 reads (26%) | called by mutect2, pindel, varscan2
- GALNT10 | c.1077_1078dup p.M360Tfs*81 | Frame Shift Ins (INS) | VAF 25/250 reads (10%) | called by mutect2, pindel
- NTN4 | c.903del p.S302Afs*99 | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | called by mutect2, pindel, varscan2
- P4HA1 | c.279_280insCAAATACT p.E94Qfs*24 | Frame Shift Ins (INS) | VAF 120/452 reads (27%) | called by mutect2, pindel, varscan2
- ROR1 | c.1841_1842insCGACGACCTTACAA p.K614Nfs*14 | Frame Shift Ins (INS) | VAF 17/112 reads (15%) | called by pindel, varscan2
- ROR1 | c.1842_1843insACGACCTTACAAC p.D615Tfs*34 | Frame Shift Ins (INS) | VAF 39/135 reads (29%) | called by mutect2, varscan2*
- RRP8 | c.1167dup p.V390Sfs*3 | Frame Shift Ins (INS) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- ULK4 | c.2279dup p.L760Ffs*4 | Frame Shift Ins (INS) | VAF 137/300 reads (46%) | called by mutect2, pindel, varscan2
- CDAN1 | c.2503C>T p.L835= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV62332883; called by muse, varscan2
- DNAH8 | c.2727T>A p.R909= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV59460247; called by muse, mutect2
- GRIA2 | c.2310A>C p.A770= | Silent (SNP) | VAF 78/359 reads (22%) | catalogued as COSV52396157; called by muse, mutect2, varscan2
- KCTD12 | c.861G>C p.S287= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58524808; called by muse, mutect2
- LILRA2 | c.108C>A p.G36= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV52193526, COSV52195468; called by muse, mutect2, varscan2
- OR56A3 | c.696C>A p.L232= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as COSV61569518; called by muse, mutect2, varscan2
- PLA2G4D | c.6G>A p.E2= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs148416017; called by muse, mutect2, varscan2
- PROSER2 | c.94C>T p.L32= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV53206563; called by muse, mutect2, varscan2
- RBM19 | c.2118A>G p.A706= | Silent (SNP) | VAF 56/174 reads (32%) | catalogued as rs1184668139, COSV55694437; called by muse, mutect2, varscan2
- RYR1 | c.1764C>A p.L588= | Silent (SNP) | VAF 18/298 reads (6%) | catalogued as COSV62102207; called by muse, mutect2
- SLC13A3 | c.1596C>T p.I532= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs941275741, COSV51715301; called by muse, mutect2, varscan2
- SLU7 | c.1758G>A p.Q586= | Silent (SNP) | VAF 24/504 reads (5%) | catalogued as COSV51788759; called by muse, mutect2
- SPTLC2 | c.399C>T p.N133= | Silent (SNP) | VAF 79/180 reads (44%) | catalogued as COSV53641228; called by muse, mutect2, varscan2
- TEC | c.1023T>A p.L341= | Silent (SNP) | VAF 140/422 reads (33%) | catalogued as COSV67405431; called by muse, mutect2, varscan2
- UTRN | c.3582C>A p.A1194= | Silent (SNP) | VAF 14/380 reads (4%) | catalogued as COSV62340023; called by muse, mutect2
- MGAT4B | c.98-80A>G | Intron (SNP) | VAF 42/146 reads (29%) | catalogued as COSV99482471; called by mutect2, varscan2
- PCDH11X | c.3033+3635C>A | Intron (SNP) | VAF 142/1130 reads (13%) | catalogued as COSV53480924; called by muse, mutect2, varscan2
- TTN | c.10303+1224G>T | Intron (SNP) | VAF 53/198 reads (27%) | catalogued as COSV60167936; called by muse, mutect2, varscan2
